Somatic mutation profile of tumor specimen C3L-04025-03 (aliquot CPT0256560006) from CPTAC case C3L-04025, project CPTAC-3 (Other and unspecified parts of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 69.2 years (25,290 days).
Specimen C3L-04025-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Buccal Mucosa; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe9a0351-1d0a-4980-8b2e-9829d7c9a391.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04025-31 (Blood Derived Normal), aliquot CPT0256700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00657e23-e387-4f47-9608-e0cd2fabbf11

The open-access MAF lists 82 somatic variants for this specimen: 58 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 14, Intron 8, Nonsense Mutation 4, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP12A | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 38/1296 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61837379; called by muse, mutect2
- ELFN2 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 34/481 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV68744804; called by muse, mutect2
- FZD7 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV53808855; called by muse, mutect2
- GCK | c.1253G>A p.S418N | Missense Mutation (SNP) | VAF 20/411 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs1422583553; called by muse, mutect2
- HYDIN | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 10/168 reads (6%) | catalogued as rs867513811; called by muse, mutect2
- KCNMA1 | c.3182G>A p.R1061Q (on ENST00000286628 / NM_001161352.2; = p.R1003Q on NM_002247.4) | Missense Mutation (SNP) | VAF 46/778 reads (6%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.999); catalogued as rs764468883, COSV54226083; called by muse, mutect2
- MFHAS1 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52284096; called by muse, mutect2
- MKI67 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 21/569 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.666); catalogued as rs1421645923, COSV64072439; called by muse, mutect2
- POM121L12 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 23/321 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200917237; called by muse, mutect2
- RPRD1A | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 25/398 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.676); catalogued as rs767361358, COSV100442356; called by muse, mutect2
- USP24 | c.6536G>A p.R2179Q | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as rs1395859636; called by muse, mutect2
- WDR45 | c.694C>T p.R232C (on ENST00000376372 / NM_001029896.2; = p.R233C on NM_007075.3) | Missense Mutation (SNP) | VAF 19/311 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59875409; called by muse, mutect2
- ZBTB7A | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 30/795 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV59326557; called by muse, mutect2
- ZFAT | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 32/766 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1438595068, COSV64738216; called by muse, mutect2
- ZSCAN4 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 20/496 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.186); catalogued as COSV56592668; called by muse, mutect2
- ADAMTS12 | c.1218A>C p.E406D | Missense Mutation (SNP) | VAF 10/279 reads (4%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.855); called by muse, mutect2
- AMY2B | c.1051A>C p.T351P | Missense Mutation (SNP) | VAF 29/627 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.197); called by muse, mutect2
- ARHGAP45 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 20/472 reads (4%) | called by muse, mutect2
- ARHGEF19 | c.1037C>A p.S346* | Nonsense Mutation (SNP) | VAF 14/324 reads (4%) | called by muse, mutect2
- CASP8 | c.1095C>A p.Y365* (on ENST00000432109 / NM_033355.3; = p.Y382* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 24/718 reads (3%) | called by muse, mutect2
- CDHR1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 44/1047 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.816); called by muse, mutect2
- COL4A6 | c.3566C>T p.P1189L | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CUX1 | c.4199G>T p.G1400V | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- ELAVL1 | c.749A>T p.N250I | Missense Mutation (SNP) | VAF 35/801 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- EPHA2 | c.926G>A p.C309Y | Missense Mutation (SNP) | VAF 68/790 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FGD4 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- GIMAP4 | c.527A>C p.Q176P | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- GLDC | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 32/990 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- GNAS | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 44/1154 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); called by muse, mutect2
- HABP2 | c.1499C>A p.P500H | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2
- ICA1 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 46/820 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.476); called by muse, mutect2
- IKBKB | c.1984T>A p.C662S | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- INHBB | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); called by muse, varscan2
- ISM1 | c.561C>A p.S187R | Missense Mutation (SNP) | VAF 22/776 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.134); called by muse, mutect2
- KIAA1328 | c.1357A>T p.M453L | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- KIF24 | c.12G>C p.W4C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, varscan2
- KIF9 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 10/239 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2
- LPP | c.1313A>G p.H438R | Missense Mutation (SNP) | VAF 20/597 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MAGEB18 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.922); called by muse, mutect2
- MEGF10 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 10/253 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); called by muse, mutect2
- MGAM2 | c.3365C>T p.S1122F | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.902); called by muse, mutect2
- MS4A6A | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.746); called by muse, mutect2
- ODF2 | c.2456G>A p.S819N (on ENST00000434106 / NM_153433.2; = p.S795N on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/392 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.153); called by muse, mutect2
- OGFOD3 | c.196G>C p.A66P | Missense Mutation (SNP) | VAF 21/766 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.133); called by muse, mutect2
- OR5T3 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 17/320 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2
- PCDHA4 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- RAD21 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.074); called by muse, mutect2
- RETSAT | c.617C>G p.P206R | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2
- RGS22 | c.3000G>T p.K1000N | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2
- SH3D21 | c.1729G>A p.E577K (on ENST00000453908 / NM_001162530.2; = p.E466K on NM_024676.5) | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.198); called by muse, mutect2
- SLC39A10 | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLITRK5 | c.2243T>C p.V748A | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.493); called by muse, mutect2
- SPON1 | c.2289G>T p.W763C | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SUZ12 | c.1631T>C p.L544P | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2
- TEP1 | c.6218G>A p.G2073E | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2
- UNC13B | c.2878C>T p.P960S | Missense Mutation (SNP) | VAF 19/318 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- UTY | c.1252T>A p.L418M | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.392); called by muse, mutect2
- ZFPM2 | c.1394T>C p.F465S | Missense Mutation (SNP) | VAF 42/1002 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.755); called by muse, mutect2
- ACD | c.1134C>T p.T378= (on ENST00000620338; = p.T289= on NM_022914.3) | Silent (SNP) | VAF 56/1232 reads (5%) | catalogued as rs372485172; called by muse, mutect2
- ADAMTSL3 | c.4785G>A p.G1595= | Silent (SNP) | VAF 24/481 reads (5%) | catalogued as COSV54473143; called by muse, mutect2
- APCDD1 | c.843G>T p.L281= | Silent (SNP) | VAF 24/406 reads (6%) | called by muse, mutect2
- APCDD1L | c.600C>T p.R200= | Silent (SNP) | VAF 34/950 reads (4%) | catalogued as rs1158284668, COSV64487132; called by muse, mutect2
- CERS3 | c.1131C>T p.P377= | Silent (SNP) | VAF 12/290 reads (4%) | called by muse, mutect2
- DDX47 | c.1230C>T p.A410= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- GNAS | c.54C>T p.I18= | Silent (SNP) | VAF 12/301 reads (4%) | catalogued as COSV58328207; called by muse, mutect2
- KIAA1755 | c.2526C>T p.R842= | Silent (SNP) | VAF 22/454 reads (5%) | called by muse, mutect2
- ONECUT3 | c.1482C>T p.A494= | Silent (SNP) | VAF 14/196 reads (7%) | called by muse, mutect2
- PCDHA2 | c.2061G>T p.A687= | Silent (SNP) | VAF 32/808 reads (4%) | catalogued as COSV100973591, COSV65364400; called by muse, mutect2
- TEX15 | c.7092C>T p.P2364= (on ENST00000256246; = p.P2747= on NM_001350162.2) | Silent (SNP) | VAF 16/171 reads (9%) | called by muse, mutect2
- TMEM140 | c.321C>T p.N107= | Silent (SNP) | VAF 54/786 reads (7%) | called by muse, mutect2
- TPO | c.2139A>G p.K713= | Silent (SNP) | VAF 36/900 reads (4%) | called by muse, mutect2
- ZFR2 | c.955C>T p.L319= | Silent (SNP) | VAF 29/856 reads (3%) | called by muse, mutect2
- ATP10A | c.3166-89C>A | Intron (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- ATP7B | c.3904-13T>A | Intron (SNP) | VAF 52/1363 reads (4%) | called by muse, mutect2
- C9orf116 | c.143+229A>G | Intron (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- CYP17A1 | c.298-30G>A | Intron (SNP) | VAF 26/520 reads (5%) | called by muse, mutect2
- EFHC1 | c.*1045T>A | 3'UTR (SNP) | VAF 5/24 reads (21%) | catalogued as rs112794529; called by muse, varscan2
- EIF4E2 | c.20+472G>A | Intron (SNP) | VAF 18/538 reads (3%) | called by muse, mutect2
- FAM234A | chr16:268931 G>A | 3'Flank (SNP) | VAF 24/962 reads (2%) | catalogued as rs1374415945; called by muse, mutect2
- TCF4 | c.550-22809G>A | Intron (SNP) | VAF 15/466 reads (3%) | called by muse, mutect2
- ZNF665 | c.-54+10406A>T | Intron (SNP) | VAF 18/606 reads (3%) | called by muse, mutect2
- ZNF665 | c.-54+10405G>T | Intron (SNP) | VAF 17/610 reads (3%) | called by muse, mutect2
